Surgical pathology report (de-identified scan), TCGA case TCGA-WR-A838, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site University of Kansas, specimen TCGA-WR-A838-01A (Primary Tumor).

[page 1 of 6]
SURGICAL PATHOLOGY REPORT

NAME:

MR #:

BILLING #:

LOCATION:

AGE:

SEX: F

DOB:

PHYSICIAN:

COPY TO:

SURG PATH #:

SPECIMEN CLASS:

ALT ID #:

DATE OF PROCEDURE:

DATE RECEIVED:

TIME RECEIVED:

DATE OF REPORT:

DATE OF PRINTING:

Material Received:

- A: anterior abdominal wall peritoneum
- B: omentum
- C: portion of left tube and ovary
- D: small bowel mesentery nodule
- E: right cul-de-sac tumor
- F: pelvic peritoneum
- G: uterus and cervix; right fallopian tube and ovary; reto-sigmoid colon
- H: small bowel tumor nodules
- I: portion of proximal colon
- J: donut
- K: peri-appendecole tumor
- L: small mesentery nodule
- M: small bowel @ 1300
- N: right diaphragmatic pleura and partial right hepatic capsule
- O: posterior common duct node
- P: gallbladder
- Q: portal peritoneum

ICD-O-3

Cryptadenocarcinoma, serous 8441/3
Site: Ovary C56.9
APD 1/16/14

History:

year-old female with a clinical history of pelvic masses.

Final Diagnosis:

- A. Fibroadipose tissue, "anterior abdominal wall peritoneum", excision:
There is no evidence of malignancy.
- B. Omentum, omentectomy:
High grade serous carcinoma.
- C. Ovary, "portion of left tube and ovary", salpingo-oophorectomy:
High grade serous carcinoma. See comment.
- D. Soft tissue, "small bowel mesentery nodule", excision:
High grade serous carcinoma.
- E. Soft tissue, "right cul-de-sac tumor", excision:
High grade serous carcinoma.
- F. Soft tissue, "pelvic peritoneum", excision:

MR #:

Page 1 of 6

Date of Printing:

SURGICAL PATHOLOGY REPORT

Order Number:

[page 2 of 6]
SURGICAL PATHOLOGY REPORT

NAME:
MR #:

SURG PATH #:
ALT ID #:

High grade serous carcinoma.

Lymph node (1): There is no evidence of malignancy (0/1).

G. Uterus, cervix, right fallopian tube and ovary, and retrosigmoid colon, resection:

High grade serous carcinoma involving the right ovary, right fallopian tube, uterine serosal surface, and the colonic serosal surface.

Uterus

Endometrium: benign endometrial polyp.

Myometrium: Leiomyomata

Cervix: No diagnostic abnormalities.

H. Fibroadipose tissue, "small bowel tumor nodules", excision:
High grade serous carcinoma.

I. Portion of proximal colon, excision:
Subserosal edema with mild acute and chronic inflammation.

J. Portion of colon, "donut", excision:
No diagnostic abnormalities.
There is no evidence of malignancy.

K. Soft tissue, "peri-appendiceal tumor", excision:
High grade serous carcinoma.

L. Soft tissue, "small mesentery nodule", excision:
High grade serous carcinoma.

M. Soft tissue, "small bowel @ 1300", excision:
High grade serous carcinoma.

N. Soft tissue, "right diaphragmatic pleura and partial right hepatic capsule", excision:
High grade serous carcinoma.

O. Lymph nodes (2), "posterior common duct node", biopsy:
There is no evidence of malignancy in two lymph nodes (0/2).

P. Gallbladder, "gallbladder", cholecystectomy:
High grade serous carcinoma involving the serosal surface.

Q. Fibroadipose tissue, "portal peritoneum", excision:
High grade serous carcinoma.

Comment:

Immunohistochemical stains show the tumor cells to be positive for p53 and WT-1 supporting the above diagnosis.

OVARY: Oophorectomy, Salpingo-Oophorectomy, Subtotal Oophorectomy or Removal of Tumor in Fragments, Hysterectomy With Salpingo-Oophorectomy

Specimen: Right ovary, Left ovary, Right fallopian tube, Uterus, Cervix, Omentum, Peritoneum, gallbladder, colon
Procedure: Bilateral salpingo-oophorectomy, hysterectomy, and tumor debulking
Lymph Node Sampling: Performed (0/3)

[page 3 of 6]
SURGICAL PATHOLOGY REPORT

NAME:
MR #:

SURG PATH #:
ALT ID #:

Specimen Integrity

Right Ovary: Capsule ruptured

Left Ovary: Fragmented

Primary Tumor Site: Bilateral ovaries

Ovarian Surface Involvement: Present

Tumor Size

Right Ovary: Cannot be determined (Fragmented)

Left Ovary: 7.2 x 7.2 x 5.3 cm

Histologic Type: Serous, carcinoma

Histologic Grade: High grade

Extent of Involvement of Other Tissues/Organs:

Right ovary: Involved

Left ovary: Involved

Right fallopian tube: Involved

Left fallopian tube: Indeterminate

Omentum: Involved

Uterus: Involved (serosal surface)

Peritoneum: Involved

Other organs/tissues: Colonic and gallbladder serosal surfaces and right hepatic capsule

Treatment Effect: N/A

Lymph-Vascular Invasion: Present

Pathologic Staging (pTNM [FIGO]) pT3cN0Mn/a

Primary Tumor (pT)

pT3c and/or N1 [IIIC]: Peritoneal metastasis beyond pelvis >2 cm in greatest dimension and/or regional lymph node metastasis

Regional Lymph Nodes (pN)

pN0: No regional lymph node metastasis

Distant Metastasis (pM)

Not applicable

The pathologic stage assigned here should be regarded as provisional, as it reflects only current pathologic data and does not incorporate full knowledge of the patient's clinical status and/or prior pathology.

Pursuant to the Quality Assurance Program at _____ this case has been concurrently reviewed by the following pathologist: _____ who agrees with the above diagnosis.

Attestation:

By this signature, I attest that I have personally formulated the final interpretation expressed in this report and that the above diagnosis is based upon my examination of the slides and/or other material indicated in this report.

Interpreted by: _____
Electronically Signed Out By
MD, Attending Physician
D.O., Resident

Gross Description:

A. Received in formalin labeled with the patient's name and "anterior abdominal wall peritoneum" is a 9.8 x 7.5 x 1.0 cm fragment of tan-yellow fibroadipose peritoneum. The specimen is serially sectioned to reveal multiple tan-white poorly demarcated areas within the cut surface. These tan-white areas measures 0.2 x 0.2 x 0.2 cm to 0.3 x 0.3 x 0.3 cm. Representative sections of the tan-white areas and peritoneum are submitted in cassettes A1 through A5.

B. Received fresh labeled with the patient's name and "omentum" is an 18.0 x 16.0 x 4.0 cm resection of omentum with multiple white-tan hemorrhagic nodules throughout the omentum. Representative sections of one of the nodules are submitted for frozen section as B1FS. Additional representative sections are submitted in cassettes B2 and B3.

C. Received fresh labeled with the patient's name and "portion of left tube and ovary" is an 89 gram fragmented salpingo-oophorectomy specimen measuring 12.0 x 7.0 x 6.0 cm in aggregate. The fragments are composed of a pink-tan solid

[page 4 of 6]
SURGICAL PATHOLOGY REPORT

NAME:
MR #:

SURG PATH #:
ALT ID #:

mass. Capsular disruption cannot be accurately assessed due to fragmented nature of the specimen but appears to be disrupted. The main fragment is serially sectioned to reveal a white-tan solid mass. There is a 1.0 x 1.0 x 1.0 cm portion of possible normal ovary identified as well as a possible fragment of fallopian tube. Representative sections of the specimen are submitted as follows:

- C2-C3 Representative sections of the mass.
- C4 Representative section of possible fallopian tube.
- C5 The portion of possible normal ovary submitted entirely.

D. Received in formalin labeled with the patient's name and "small bowel mesentery nodule" is an intact and unoriented 5.0 x 4.0 x 1.0 cm portion of soft yellow lobulated adipose tissue which demonstrates an ill-defined 3.5 x 2.0 x 1.2 cm tan-pink, rubbery and focally friable nodule. The specimen is serially sectioned to reveal cut surfaces of the lesion which are white-pink, smooth with focal, friable and hemorrhagic areas. Representative tissue is submitted in cassettes D1 and D2.

E. Received in formalin labeled with the patient's name and "right cul-de-sac tumor" is a 19.5 x 4.5 x 1.0 cm aggregate of yellow adipose tissue that demonstrates a 4.0 x 3.5 x 0.8 cm mass. The mass is representative section to reveal a tan-white rubbery appearance. Representative sections are submitted in cassettes labeled E1 and E2.

F. Received in formalin labeled with the patient's name and "pelvic peritoneum" is a 7.0 x 4.0 x 3.5 cm intact irregular unoriented portion of soft tan-yellow fibroadipose tissue which demonstrates 3.0 x 3.0 x 2.0 cm tan-pink rubbery and focally friable lesion. The specimen is serially sectioned to reveal a white-pink smooth and solid lesion. Representative tissue is submitted in cassettes F1 and F2.

G. Received fresh labeled with the patient's name and "uterus, cervix, right ovary and fallopian tube and rectosigmoid colon" is a 23.1 x 20.0 x 6.2 cm pelvic resection. The resection consists of a uterus that weighs 308 grams and measures 10.0 cm from uterine fundus to cervical os, 6.2 cm from cornu to cornu and 5.8 cm from anterior to posterior. The serosa is tan-pink with multiple adherent tan-white firm nodules. The cervical os is slit like in shape and measures 0.8 cm. The cervical os is probed patent, and the uterus is bisected coronally to reveal a 5.4 x 2.2 cm endometrial cavity and a 1.5 x 1.2 cm endocervical cavity. The posterior endometrial cavity contains a 2.8 x 1.5 x 0.4 cm polypoid lesion. This lesion does not appear to invade into the myometrium. The uterus is serially sectioned to reveal an average endometrial thickness of 0.3 cm and an average myometrial thickness of 2.5 cm. The myometrium contains multiple well-circumscribed tan-white whorled nodules consistent with leiomyomata. These nodules range in size from 0.5 x 0.5 x 0.5 cm to 2.7 x 1.4 x 1.3 cm. A representative section of the polypoid lesion is submitted for frozen section in cassette G1FS.

Attached to the uterus is an 8.6 cm right fimbriated fallopian tube with a diameter of 0.3-2.6 cm. The fallopian tube contains a cystic area that measures 3.5 x 2.6 x 1.7 cm. This area is tan-red and soft. The specimen is serially sectioned to reveal that the enlarged area contains a clear serous fluid. The remainder of the fallopian tube has a pinpoint lumen and is grossly unremarkable. The fimbriated end of the fallopian tube is enlarged and contains to be grossly involved by a tumor. Attached to the fallopian tube is a 184 gram ovarian mass. This mass measures 7.2 x 7.2 x 5.3 cm. The external surface is tan-pink with multiple projections through the capsule. The largest capsular projection measures 2.0 x 1.1 x 0.6 cm and is inked black. The specimen is serially sectioned to reveal a firm tan-white cut surface with multiple cysts ranging in size from 0.3 x 0.2 x 0.2 cm to 2.5 x 2.0 x 2.0 cm. The cysts are filled with a range of fluids from clear yellow serous fluid to hemorrhagic material. The cut surface contains multiple foci of hemorrhagic and necrotic areas. No ovarian parenchyma can be grossly seen. The mass does not appear to grossly invade into the uterus. The mass also abuts the portion of colon but does not appear to grossly invade. The cyst walls measures 0.2 cm in thickness. The attached colon measures 20.4 cm in length by 2.6 cm in diameter. The colon contains staple lines at the resection margin. The staple lines are removed. The specimen is opened along the serosal aspect to reveal a grossly unremarkable tan-brown mucosa. The specimen is submitted as follows:

- G2 12:00 Cervix.
- G3 6:00 Cervix.
- G4 Anterior lower uterine segment.
- G5 Full thickness anterior wall, one slice bisected.
- G6 Posterior lower uterine segment.
- G7 Full thickness posterior wall.
- G8 Representative sections of the leiomyomata.
- G9-G10 Representative sections of the ovarian mass to the uterine serosa.
- G11 Entire unremarkable fallopian tube serially sectioned.
- G12-G13 Representative sections from the dilated fallopian tube showing relationship to the ovarian mass.
- G14 Representative section from the fimbriated end of the fallopian tube.
- G15 Representative section of the ovarian mass showing the capsular protrusion inked black.
- G16-G17 Additional representative sections of ovarian mass.
- G18-G19 Representative sections of the mass to the colonic mucosa.

Date of Printing:

MR #:

Page 4 of 6

SURGICAL PATHOLOGY REPORT

[page 5 of 6]
SURGICAL PATHOLOGY REPORT

NAME:
MR #:

SURG PATH #:
ALT ID #:

G20 Distal colonic resection margin shaved.
G21 Proximal colonic resection margin shaved.
G22 Representative section of colonic mucosa.
G23 Representative section of the posterior polypoid endometrial lesion.

H. Received fresh labeled with the patient's name "small bowel tumor nodules" is an aggregate of pink-tan soft tissue measuring 3.0 x 2.0 x 1.0 cm in aggregate. Representative sections are submitted for . Additional representative section is submitted in cassette H1.

I. Received in formalin labeled with the patient's name "portion of proximal colon" is a 3.5 cm portion of colon with a diameter of 2.5 cm. The external surface is pink-tan and smooth with epiploic fat attached. Staple lines are removed and the bowel is opened to reveal an unremarkable pink-tan mucosa. The surrounding fibroadipose is soft tissues to reveal a marked edematous surface. No mass lesions are seen in the specimen. Sections are submitted as follows:

I1-2 Representative sections of resection margin.

I3-4 Representative section of the unremarkable colonic mucosa and underlying edematous tissue.

J. Received in formalin labeled with the patient's name and "donut" are two donut-shaped pieces of bowel, one measuring 1.5 x 1.0 x 0.5 cm and measuring 1.0 x 1.5 x 0.5 cm. The larger donut is trisected and submitted entirely in cassettes J1 and J2. The smaller donut is bisected and submitted entirely in cassette J3.

K. Received in formalin labeled with the patient's name and "peri-appendiceal tumor" is a 5.0 x 0.5 x 0.5 cm piece of pink-tan soft tissue and yellow fibroadipose tissue. Attached to the fibroadipose tissue is a 5.0 x 3.0 x 1.0 cm portion of red-tan hemorrhagic soft tissue. No grossly identifiable appendix is identified. Representative sections of the hemorrhagic area submitted in cassettes K1-K3. The fibroadipose tissue is serially sectioned to reveal no discrete mass lesions or gross abnormalities.

L. Received in formalin labeled with the patient's name and "small mesentery nodule" is a 2.5 x 1.0 x 1.0 cm piece of pink-tan soft tissue. The specimen is serially sectioned to reveal a pink-tan solid cut surface. Representative section of the specimen submitted in cassette L1.

M. Received in formalin labeled with the patient's name and "small bowel" are two fragments of firm tan-pink tissue measuring 1.2 x 1.0 x 0.6 cm and 1.5 x 1.0 x 0.7 cm. The fragments are submitted entirely in cassettes M1 and M2.

N. Received fresh labeled with the patient's name and "right diaphragmatic pleura and partial right hepatic capsule" is a 16.4 x 8.5 x 1.4 cm fragment of tan-pink fascia. The specimen contains multiple firm nodules embedded within the smooth tan-pink surface. The specimen is serially sectioned to reveal that the nodules are firm tan-white on their cut surface. Representative sections are submitted in cassettes N1-N4.

O. Received in formalin labeled with the patient's name and "posterior common duct node" is a 2.1 x 1.6 x 0.9 cm fragment of tan-yellow fibroadipose tissue. The specimen is bisected and submitted entirely in cassette O1.

P. Received in formalin, labeled with the patient's name and "gallbladder" is a 10.5 x 4.0 x 4.0 cm cholecystectomy specimen. The serosa is green-brown and smooth to ragged. The gallbladder is opened to reveal a green velvety mucosa. The gallbladder wall ranges in size from 0.1 cm up to 0.4 cm. The cystic duct remnant contains a metallic staple, but is otherwise patent. No calculi are identified. Representative sections from the gallbladder body and fundus, and a shave of the cystic duct remnant are submitted in cassette P1.

Q. Received in formalin labeled with the patient's name and "portal peritoneum" is a 3.0 x 2.0 x 1.0 cm piece of yellow-tan fibroadipose tissue. No discrete mass lesions are identified. The specimen is submitted entirely in cassettes Q1 and Q2.

D.O., Resident

Intraoperative Consultation:

B1FS, omentum, "omentum":

Poorly differentiated carcinoma.

G1FS, uterus, "uterus, cervix, right ovary and fallopian tube and rectosigmoid colon":

Benign endometrial polyp.

, Attending Physician

Date of Printing:

MR #:

Page 5 of 6

SURGICAL PATHOLOGY REPORT

[page 6 of 6]
SURGICAL PATHOLOGY REPORT

NAME:
MR #:

SURG PATH #:
ALT ID #:

If immunohistochemical stains and/or in situ hybridization are cited in this report, the performance characteristics were determined by the
in compliance with CLIA'88
regulations. Some of these tests rely on the use of "analyte specific reagents" and are subject to specific labeling requirements by the FDA. Known
positive and negative control tissues demonstrate appropriate staining. This testing was developed by the
It has not been cleared or approved by the FDA. The FDA has determined that such clearance or approval
is not necessary.

Date of Printing:

MR #:

Page 6 of 6

SURGICAL PATHOLOGY REPORT

Source: NCI Genomic Data Commons file c7482c79-695e-4a9e-ba74-a15ebe0d8b93 (TCGA-WR-A838.8F364931-727D-4099-A1D2-E96C61461479.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).